Surgical pathology report (de-identified scan), TCGA case TCGA-A5-A0R7, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site Cedars Sinai, specimen TCGA-A5-A0R7-01A (Primary Tumor).

[page 1 of 4]
RESULTS FOR SELECTED GRID CELL, SUMMARY
Printed

125-0-3

Adenocarcinoma, Endometrioid, NOS

8380/3

Site: endometrium
c54.1

11/22/10

Collect D/T=

SURGICAL PATHOLOGY

Modifiers: (1 of 1)

SURGICAL PATHOLOGY:
COPath Specimen

Source:

- A: Right Tube \T\ ovary, (Permanent)
B: Left Tube \T\ ovary
C: Uterus
D: Left Pelvic lymph node
E: Left Peri-aortic, (Frozen section)

F: Right Pelvic lymph node

Final Diagnosis

- A. Fallopian tube and ovary, right (salpingo-oophorectomy):
-Ovary with endosalpingiosis and no significant histopathologic abnormalities.
-Fallopian tube with no significant histopathologic abnormalities.

- B. Fallopian tube and ovary, left (salpingo-oophorectomy):
-Ovary with follicular cyst and benign glandular rest.
-Fallopian tube with no significant histopathologic abnormalities.

- C. Uterus (total abdominal hysterectomy):
-Adenocarcinoma, endometrioid type, grade 2/3.
-Tumor is seen extending into the deep myometrium involving 40% of the myometrial wall (1cm invasion with wall thickness 2.5 cm.)
-Cervical margin of resection appears clear.
-Bilateral parametrial margins of resection appear clear.
-No definite evidence of lymph-vascular space invasion.
-With regard to invasion of the lower uterine segment by carcinoma, this is pending additional sections.

- D. Lymph node, left pelvic (biopsy) -No evidence of malignancy in two lymph nodes examined.

- E. Periaortic, left (biopsy):
-No evidence of malignancy in seven lymph nodes examined.

- F. Lymph node, right pelvic (biopsy):

[page 2 of 4]
SURGICAL PATHOLOGY
(Continued)

SURG Adm:

G. Periaortic, right (biopsy):
-No evidence of malignancy in one lymph node examined.

H. Omentum (omentectomy):
-Psammoma bodies identified.
-No evidence of malignancy.

***Electronically Signed Out

Clinical History
Grade 3 endometrial cancer.

Pre Operative Diagnosis
Grade 3 endometrial cancer.

Operation Performed
Ex-lap, TAH, BSO, staging.

Post Operative Diagnosis
Same.

Intraoperative Diagnosis
Frozen Section

Lymph node, left periaortic (biopsy):
-No evidence of malignancy.

A.D.

Gross Description The specimen is submitted in eight parts, all are labeled with the patient's name.

Specimen A is labeled "right tube and ovary" and consists of one ovary, measuring 3 x 1.5 x 1 cm, as well as a 4 x 0.5 cm in diameter portion of fallopian tube. Representative sections of fallopian tube are submitted in cassette A1. On cut section, no focal abnormalities are noted in the ovary.
Representative

[page 3 of 4]
Adm:

Sex:F

E

SURGICAL PATHOLOGY

(Continued)

Sections of ovary are submitted in cassette A2.

a

n

1 d

1

4 x

0.5 cm

Specimen B is labeled IIleft fallopconsists of one, 3 x 4 x 0.5 cm
.8 x 1.5 cm as well as
in diameter fallopian tube. On cut section, no abnormalities are noted in the ovary.
Representative sections of fallopian tube are submitted in cassette B1 and ovary in cassette B2.

Specimen C is labeled IIuterus^{II} and consists of one, 278 gram uterus. The myometrium measures 2 cm in thickness and there is an exophytic tumor extending 1 cm above the apparent myometrium.

The tumor grossly does not appear to extend down into the lower uterine segment. The cervix appears clear. The specimen is inked. Sections of the cervical margin of resection are submitted in cassettes C1 and C2. Sections of the right parametrial margin of resection are submitted in cassette C3. Sections of the left parametrial margin of resection are submitted in cassette C4. Sections of the lower uterine segment are submitted in cassettes C5 and C6. On further sectioning of the tumor, it appears to be invading the myometrium with the myometrial thickness of 2.5 cm. Tumor is seen invading 1 cm into the myometrium with 1.5 cm of remaining uninvolved myometrium. Sections of tumor in this region are submitted in contiguous sections in C7 and C8 and C9 and C10 showing the deepest penetration of tumor.

Specimen D is labeled IIleft pelvic lymph node^{II} and consists of multiple fragments of red-brown tissue that measure in aggregate 1 x 1 x 0.5 cm. Representative nodes are submitted in cassette

D.

Specimen E is labeled IIleft periaortic lymph nodes^{II} and are submitted for frozen section. The frozen section specimen is entirely resubmitted in cassette E.

Specimen F is labeled IIright pelvic lymph node^{II} and consists of one, 2 x 2 x 0.5 cm portion of tan tissue, which is examined for lymph nodes and representative nodes are submitted in cassettes F1 and F2.

Specimen G is labeled IIright periaortic lymph node^{II} and consists of one, 2 x 2 x 0.5 cm portions of tan tissue, which is sectioned and representative nodes are submitted in cassette G.

[page 4 of 4]
SURGICAL PATHOLOGY (Continued) Adm:

Specimen H is labeled "omentum" and consists of one apparent partial omentectomy specimen, measuring 5 x 5 x 0.2 cm. On palpation, no definite nodules are identified. On cut section, no nodules are identified. Representative sections are submitted in cassette H1 through H4.

Microscopic Description
Microscopic Examination was performed.

IHPAA Discrepancy		☒
Qual/Synchronous/Other Noted		☒

Source: NCI Genomic Data Commons file 59785e82-45e5-4255-8fb8-0dc1493d116b (TCGA-A5-A0R7.3BBA7591-082A-44CE-829F-23D16A91772D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).